HCMI case HCM-SANG-0536-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/9d868cf7-4c23-45f6-9897-015db647fc6e

Demographics
Sex at birth: male; Days to birth: -22,828 days (62.5 years before the index date).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.6; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Descending colon; Classification of tumor: primary; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Sites of involvement: Liver; Uicc clinical stage: Stage IVA; Uicc pathologic m: M0; Uicc pathologic n: N1c; Uicc pathologic stage: Stage IIIA; Uicc pathologic t: T2; Uicc staging system edition: 7th.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Oxaliplatin; Treatment intent type: Neoadjuvant; Days to treatment start: 138 days.

Follow-up (1 entry)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples)
- Sample HCM-SANG-0536-C18-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
- Sample HCM-SANG-0536-C18-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Samples HCM-SANG-0536-C18-85A-01D-A80T-32, HCM-SANG-0536-C18-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
